Somatic mutation profile of tumor specimen TCGA-AH-6903-01A (aliquot TCGA-AH-6903-01A-11D-1924-10) from TCGA case TCGA-AH-6903, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 46.6 years (17,030 days).
Specimen TCGA-AH-6903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dfa03de-bdfa-40ef-9f05-dfb37e056cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6903-10A (Blood Derived Normal), aliquot TCGA-AH-6903-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/868a4a6c-3386-4ed4-8167-1e9f46e2261f

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Nonsense Mutation 5, Splice Site 2, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs183161718, CM164826, COSV99656660; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- FBXW7 | c.670C>T p.R224* (on ENST00000281708 / NM_001349798.2; = p.R144* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 60/265 reads (23%) | hotspot (GDC flag); catalogued as rs1406877044, COSV55899023; called by muse, mutect2, varscan2
- GABRB2 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1554093884, COSV50956265; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 37/133 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 57/237 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 43/72 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TRPC6 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs1565221699, COSV100723532; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.4525C>T p.R1509W (on ENST00000373658 / NM_001364857.2; = p.R1508W on NM_001294335.2) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs749363644, COSV57079587; called by muse, mutect2, varscan2
- ALPL | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as CM980080, COSV66376712; called by muse, mutect2, varscan2
- APC | c.3022del p.I1008Yfs*14 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | catalogued as COSV57354716, COSV57355226; called by mutect2, pindel, varscan2
- ARNTL2 | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667641; called by muse, mutect2
- ASTN2 | c.3563C>T p.T1188M (on ENST00000313400 / NM_001365069.1; = p.T1137M on NM_014010.5) | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as rs762408231, COSV56004007; called by muse, mutect2, varscan2
- BRCA2 | c.10202C>T p.T3401M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as rs55853199, HM971469, COSV58414221; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CCDC141 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs757788800, COSV55369654; called by muse, mutect2, varscan2
- CCDC85A | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs746039716, COSV68156044; called by muse, mutect2, varscan2
- CECR2 | c.4148A>T p.Y1383F (on ENST00000342247 / NM_001290047.2; = p.Y1199F on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV52849477; called by muse, mutect2, varscan2
- CENPE | c.7603G>A p.G2535S | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756483643, COSV54387672; called by muse, mutect2, varscan2
- CHRM2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1161870506, COSV57786111; called by muse, mutect2, varscan2
- CXCR1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as rs940418262, COSV55281110; called by muse, mutect2, varscan2
- DBX2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368330243; called by muse, mutect2, varscan2
- DNAH8 | c.7685C>T p.T2562I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.221); catalogued as COSV59484835; called by muse, mutect2, varscan2
- EPHA3 | c.662A>T p.Q221L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV60730534; called by muse, mutect2, varscan2
- EPHA3 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV60730546; called by muse, mutect2, varscan2
- FHOD3 | c.1513C>T p.R505W (on ENST00000359247 / NM_001281739.3; = p.R522W on NM_025135.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs763622401, COSV57190409; called by muse, mutect2, varscan2
- FLG | c.6409A>C p.T2137P | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100911325; called by muse, mutect2
- GPR82 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV56888378; called by muse, mutect2, varscan2
- GRAMD1B | c.2115G>A p.M705I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59211423; called by muse, mutect2, varscan2
- HSF4 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs371071221; called by muse, mutect2, varscan2
- HTR3E | c.781C>A p.L261M (on ENST00000415389 / NM_001256613.1; = p.L276M on NM_182589.2) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58946434, COSV58949251; called by muse, mutect2, varscan2
- IL3 | c.336+1G>A p.X112_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV57308542, COSV57310028; called by muse, mutect2, varscan2
- KRT17 | c.935T>A p.I312K | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60862297; called by muse, mutect2, varscan2
- KRTAP20-1 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 124/540 reads (23%) | PolyPhen possibly damaging (0.9); catalogued as COSV58168728; called by muse, mutect2, varscan2
- LAMA5 | c.2407G>A p.V803M | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs202214661, COSV53370196; called by muse, mutect2, varscan2
- LIFR | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54701441; called by muse, mutect2, varscan2
- MAP4K3 | c.2615G>A p.S872N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55719486; called by muse, mutect2, varscan2
- MBNL3 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV63731844; called by muse, mutect2
- MOGAT1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71480161; called by muse, mutect2, varscan2
- MRTFA | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as rs371934037; called by muse, mutect2, varscan2
- NYNRIN | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs373042156; called by muse, mutect2, varscan2
- OR4A5 | c.675C>G p.Y225* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as rs772202429, COSV60525049; called by muse, mutect2, varscan2
- OR51F1 | c.534T>A p.C178* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV58581065; called by muse, mutect2, varscan2
- PABPC5 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs867499748, COSV57040330; called by muse, mutect2, varscan2
- PAPOLB | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1562454376, COSV68201462; called by muse, mutect2, varscan2
- PCDH18 | c.2542A>C p.S848R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100787028, COSV61271459; called by muse, mutect2, varscan2
- POP1 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs140243288, COSV62894329; called by muse, mutect2, varscan2
- PRMT3 | c.1579A>C p.T527P | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV58181302; called by muse, mutect2, varscan2
- QRFPR | c.562-1G>A p.X188_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV57680530; called by muse, mutect2, varscan2
- SCN9A | c.4891C>T p.R1631C (on ENST00000303354; = p.R1620C on NM_002977.3) | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202155356, COSV57622496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTA1 | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV99458640; called by muse, mutect2, varscan2
- TCF12 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99976926; called by muse, mutect2
- TENM4 | c.6892C>T p.R2298W | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763360287, COSV53624865; called by muse, mutect2, varscan2
- TFDP1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs773698836, COSV100945783; called by muse, mutect2, varscan2
- WWP1 | c.2336G>A p.G779D | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285827381, COSV55364920; called by muse, mutect2, varscan2
- XCR1 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as COSV58570972; called by muse, mutect2, varscan2
- ZNF552 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV66971990; called by muse, mutect2, varscan2
- PHLDA1 | c.752_753dup p.F252Tfs*5 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel
- CALCR | c.1014G>T p.V338= (on ENST00000649521 / NM_001164737.2; = p.V322= on NM_001742.4) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV64012712; called by muse, mutect2, varscan2
- CDK5R1 | c.898C>A p.R300= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV57831982; called by muse, mutect2, varscan2
- CRELD1 | c.534C>T p.S178= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs752287273, COSV55978756; called by muse, varscan2
- CUBN | c.9681T>C p.S3227= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs773439837, COSV64728907; called by muse, mutect2, varscan2
- EVA1A | c.111C>T p.Y37= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV52063017; called by muse, mutect2, varscan2
- GALNT17 | c.684C>T p.R228= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs148070000; called by muse, mutect2, varscan2
- GRIK2 | c.915G>A p.P305= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs145542805, COSV100028502; called by muse, mutect2, varscan2
- GRM1 | c.2952C>T p.S984= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV51139891; called by muse, mutect2, varscan2
- GTPBP3 | c.780G>A p.A260= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1241764362, COSV50202366; called by muse, mutect2, varscan2
- HECW1 | c.2313C>T p.D771= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs532202982, COSV67820610; called by muse, mutect2, varscan2
- IGSF1 | c.3204C>T p.S1068= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV63840842; called by muse, mutect2, varscan2
- LAMB3 | c.231C>T p.Y77= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV61920233; called by muse, mutect2, varscan2
- MAGI2 | c.1929C>T p.G643= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs368148275, COSV62697082; called by muse, mutect2, varscan2
- NR1I3 | c.993G>A p.G331= (on ENST00000367982 / NM_001077480.3; = p.G327= on NM_005122.5) | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- OFD1 | c.1500C>T p.F500= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs775685381, COSV60799356; called by muse, varscan2
- PAG1 | c.420C>T p.S140= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs929622305, COSV55055357; called by muse, mutect2, varscan2
- PCDHGA2 | c.843A>G p.L281= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PDIA6 | c.1218C>A p.I406= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV55354258; called by muse, mutect2, varscan2
- PRRT2 | c.702G>A p.G234= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV54887012; called by muse, mutect2, varscan2
- PRSS38 | c.18C>T p.S6= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs758788764, COSV64541688; called by muse, mutect2, varscan2
- WDSUB1 | c.558C>T p.C186= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs148455296; called by muse, mutect2, varscan2
- DCHS2 | n.3172A>G | RNA (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100251378; called by muse, mutect2, varscan2
